FM case AD4391 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Transitional Cell Papillomas and Carcinomas.
https://portal.gdc.cancer.gov/cases/50e67e66-7b71-4fdf-8a5c-324a633b3e83

Male, 77.3 years: Urothelial carcinoma, NOS (ICD-O-3 8120/3); specimen biopsied or resected from the vertebral column. Sample type: Tumor.
